Gene-level copy-number profile of specimen HCM-CSHL-0467-C56-85M from HCMI case HCM-CSHL-0467-C56, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; AJCC pathologic stage: Stage IIIC; FIGO stage: Stage III; Tumor grade: High Grade.
Specimen HCM-CSHL-0467-C56-85M: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 2.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 88ae1478-b974-48d0-9fd3-e8676b5d5b0e.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-CSHL-0467-C56-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,234 have no estimate.
https://portal.gdc.cancer.gov/files/8a711db5-69d0-41fc-b767-8704d95d3eb3

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 3; copy number 1: 3,616; copy number 2: 21,483; copy number 3: 22,915; copy number 4: 8,482; copy number 5: 825; copy number 6: 328; copy number 7: 223; copy number 8: 10; copy number 9: 472; copy number 10: 32.

Homozygous deletions (total copy number 0; autosomes only): 3 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:29,636,486–29,826,711, 2 genes: AL354676.1, ME2P1.
- chr16:33,802,764–33,803,217, 1 gene: IGHV3OR16-12.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 737 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:111,429,324–113,278,921, 57 genes, copy number 7–10 (within-gene range 2–10): AC017002.3, AC017002.2, SOCAR, DBF4P2, AC017002.1, ANAPC1, RPL34P8, AC093166.1, CENPNP2, MIR4771-2, AC093166.2, EEF1E1P1, MERTK, RN7SL297P, RTRAFP1, SLC30A6P1, AC093675.1, TMEM87B, AC093675.2, FBLN7, AC092645.1, ZC3H8, AC092645.2, ZC3H6, NDUFB4P6, AC115115.1, RGPD8, TTL, POLR1B, Y_RNA, CHCHD5, AC012442.2, AC012442.1, AC079922.1, AC079922.2, SLC20A1, NT5DC4, CKAP2L, IL1A, IL1B, AC079753.1, XIAPP3, IL37, CDK8P2, IL36G, HMGN2P23, POLR2DP1, IL36A, IL36B, IL36RN, IL1F10, RNU6-1180P, IL1RN, PSD4, AC016683.1, PAX8-AS1, PAX8.
- chr2:113,577,382–114,420,302, 26 genes, copy number 7–10: FAM138B, AL078621.2, MIR1302-3, WASH2P, DDX11L2, AL078621.1, RPL23AP7, RABL2A, SNRPA1P1, ACRP1, AC017074.2, AC017074.1, RNU6-744P, SLC35F5, MIR4782, AC104653.2, AC104653.1, AC110769.2, ACTR3, AC110769.3, LINC01191, AC110769.1, U3, AC010982.1, SEPHS1P7, RNU2-41P.
- chr2:171,517,270–171,558,129, 2 genes, copy number 7: RPS15P4, CYBRD1.
- chr3:75,370,448–75,670,185, 22 genes, copy number 7: OR7E55P, AC139453.2, LSP1P2, AC139453.1, ALG1L6P, FAM86DP, LINC02018, ENPP7P2, SNRPCP10, AC133041.1, RPS3AP15, AC108724.1, OR7E121P, UNC93B3, RPL23AP49, AC108724.2, CLUHP10, MIR1324, AGGF1P3, RARRES2P1, FRG2C, DUX4L26.
- chr19:12,763,003–12,872,740, 1 gene, copy number 9 (within-gene range 2–9): HOOK2.
- chr19:12,787,128–13,633,025, 40 genes, copy number 9 (within-gene range 9–10): MIR5684, JUNB, PRDX2, AC018761.2, THSD8, RNASEH2A, RTBDN, AC020934.1, MAST1, MIR6794, DNASE2, AC020934.2, KLF1, GCDH, RPS6P25, SYCE2, MIR5695, FARSA, FARSA-AS1, CALR, MIR6515, AC092069.1, RAD23A, GADD45GIP1, DAND5, NFIX, AC138474.1, AC007787.1, AC007787.2, LYL1, TRMT1, NACC1, AC005546.1, AC011446.1, STX10, IER2, AC011446.3, AC011446.2, RPL12P42, CACNA1A.
- chr20:38,805,697–64,327,972, 589 genes, copy number 7–9 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,272. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
